Gene-level copy-number profile of tumor specimen TCGA-IB-7646-01A from TCGA case TCGA-IB-7646, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.6 years (22,148 days).
Specimen TCGA-IB-7646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.539c3766-8012-4745-b477-8c1c3050575c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7646-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd392be0-073d-4ec8-8d46-244a04858424

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 368; copy number 1: 25,538; copy number 2: 33,012; copy number 3: 901.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-7646-01A-11D-2153-01): tumor purity 0.37, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 275 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,905,651–2,089,211, 3 genes: RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes: CNTN4-AS2, AC087427.1.
- chr3:29,926,811–30,699,576, 9 genes: RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2.
- chr4:17,810,979–19,938,448, 12 genes (within-gene range 0–1): NCAPG, LCORL, KRT18P63, AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1.
- chr4:163,471,095–165,060,554, 33 genes: TKTL2, TMA16, MARCHF1, AC093788.1, RN7SKP105, YWHAQP4, AC105250.1, ANP32C, AC074198.1, RNU6-284P, CHORDC1P3, SMIM31, RNU6-668P, APELA, TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P.
- chr6:149,817,937–152,637,801, 59 genes (within-gene range 0–1): AL355312.5, LRP11, AL355312.3, RAET1E-AS1, CCT7P1, RAET1E, RAET1E-AS1, AL355312.1, RAET1G, AL583835.2, ULBP2, AL583835.1, ULBP1, AL355497.1, BTF3P10, RAET1K, RAET1L, RAET1M, AL355497.2, PHBP1, ULBP3, PPP1R14C, AL355497.3, RNU4-7P, IYD, SSR1P1, AL451061.1, PLEKHG1, AL450344.3, AL450344.1, AL450344.2, PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1.
- chr7:151,556,124–152,129,686, 11 genes (within-gene range 0–1): PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4.
- chr8:22,114,419–23,117,445, 43 genes: HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2, PIWIL2, SLC39A14, AC105910.1, RNU6-336P, PPP3CC, AC087854.1, BTF3P3, SORBS3, AC037459.4, AC037459.3, PDLIM2, AC037459.1, C8orf58, CCAR2, AC037459.2, BIN3, AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C.
- chr9:20,999,509–22,214,672, 55 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:17,315,421–20,351,100, 40 genes (within-gene range 0–1): ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1, MALRD1, UBE2V2P1, AL590378.1, HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2, AMD1P1.
- chr13:53,099,397–53,801,489, 8 genes (within-gene range 0–1): LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 23,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
